Gene-level copy-number profile of tumor specimen C3N-00492-04 from CPTAC case C3N-00492, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 49.3 years (17,993 days).
Specimen C3N-00492-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a638bca7-4185-470e-bb1d-71aa6de1f9ed.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00492-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/fc1d1e99-442f-4354-b586-d383223c9b4d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 22,386; copy number 2: 35,902; copy number 3: 79; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr2:130,048,426–130,129,222, 5 genes (within-gene range 0–1): CYP4F27P, POTEF, AC018865.1, POTEF-AS1, RNU6-1049P.
- chr17:38,936,432–38,967,403, 1 gene: FBXO47.
- chr21:9,068,361–9,129,752, 3 genes (within-gene range 0–1): TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 20,042. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
